Surgical pathology report (de-identified scan), TCGA case TCGA-UB-A7MB, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UCSF, specimen TCGA-UB-A7MB-01A (Primary Tumor).

[page 1 of 5]
Results

Surgical Pathology

(enter 1 per line): 1. gallbladder, 2. left hepatic lobe

Result Information

Status (Last updated Date/Time)

Accession #

SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Sex: Male

Soc. Sec. #:

Accession #:

Visit #:

Service

Receive

Locatio

Client:

Physici

ICD-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver C22.0

9/20/13

FINAL PATHOLOGIC DIAGNOSIS

A. Gallbladder, cholecystectomy:

1. Gallbladder with no significant pathologic abnormalities.
2. No tumor identified.

B. Liver, left lobe, partial hepatectomy:

1. Hepatocellular carcinoma, moderately to poorly differentiated, present as three discrete foci (4.9, 3.0, and 0.8 cm in greatest dimension) in resected lobe of liver; see comment.
2. No tumor identified at surgical resection margins.
3. Non-neoplastic hepatic parenchyma showing minimal macrovesicular steatosis.

COMMENT:

The three hepatic tumors generally resemble hepatocellular carcinoma, but because of focal poorly differentiated areas (most notable in block B5 of the 0.8 cm nodule), immunoperoxidase stains for Arginase-1 and CK19 were performed on block B5 in order to exclude the possibility of a combined hepatocellular and cholangiolar carcinoma. These stains show the tumor cells to be diffusely positive for Arginase-1 and entirely negative for CK19. A mucicarmine stain performed on block B5 is negative in the tumor cells. A reticulin stain performed on block B5 confirms lack of normal hepatocellular architecture among the tumor

[page 2 of 5]
cells. Together, these findings support the diagnosis of hepatocellular carcinoma. Dr. has reviewed selected slides from this case, including the immunoperoxidase stains, and agrees with the diagnosis of moderately to poorly differentiated hepatocellular carcinoma.

Liver Tumor Synoptic Comment:

- Tumor type: Hepatocellular carcinoma (see above discussion).
- Histologic grade: Moderate to poorly differentiated (grade 2-3/3; see above discussion).
- Tumor size (maximum diameter of largest lesion): 4.9 cm.
- Tumor necrosis: None identified.
- Multifocality (more than one tumor separated by nontumorous liver parenchyma): Present.
- Estimated total tumor diameter of all HCC foci: 8.7 cm.
- Vascular invasion: Focal lymphatic invasion present (slide B1); no blood vessel invasion identified.
- Hepatic capsule: Tumor focally abuts but does not penetrate through overlying liver capsule.
- Local extension of tumor: Confined to liver.
- Hepatic surgical margins: Negative for tumor; tumor is 0.7 cm from nearest margin.
- Non-neoplastic liver: Minimal steatosis, no significant fibrosis (confirmed by trichrome stain performed on block B7).
- Hepatocellular nodules (in cirrhotic liver): Not applicable (no cirrhosis present).
- Lymph node status: Not applicable (no lymph nodes sample by surgical procedure).
- AJCC Stage: pT2bNX.

Specimen(s) Received
A:Gallbladder
B:Left hepatic lobe

Clinical History

The patient is a year-old man. Review of the patient's electronic medical record reveals that he has a longstanding history of Crohn's disease, and was recently found to have multiple liver lesions on imaging studies, the largest measuring 6 cm. A prior needle core biopsy demonstrated hepatocellular carcinoma). The patient now undergoes left hepatic lobectomy.

Gross Description

The case was received in two parts, each labeled with the patient's name and medical record number.

Part A is received fresh and additionally labeled "gallbladder," and consists of an intact gallbladder (7.5 x 3 x 2.5 cm). No calculi are identified. The lumen contains thick yellow-tan bile. The mucosa is tan and velvety with diffuse pinpoint yellow speckling present. The wall is flaccid and averages 0.3 cm in thickness. The serosa is grey-pink and glistening. The hepatic bed is tan-yellow and roughened. The cystic duct margin (0.3 cm in diameter; inked black) is patent. No lymph nodes are identified. No tumor is identified. Representative sections of the cystic duct, body and fundus are submitted in cassette A1.

Part B is received fresh and additionally labeled "left hepatic lobe."

[page 3 of 5]
[REDACTED]

SPECIMEN TYPE: Partial hepatectomy.

SIZE: 974 gm; 16.5 cm from right to left x 23.2 cm from anterior to posterior x 5.1 cm from anterior to inferior.

GROSS ABNORMALITIES: Three well-circumscribed, soft, white-tan lesions are noted within the liver parenchyma. Nodule #1 (4.7 x 4.5 x 4.9 cm) is noted in segment 4B, abutting the overlying capsule and approximately 2 cm from the cauterized resection margin. Nodule #2 (3 x 2.5 x 1 cm) is present in segment 4A, 1.7 cm from the overlying capsule and 0.7 cm from the cauterized resection margin. Nodule #3 (0.8 x 0.7 x 0.3 cm) is present in segment 3, 0.3 cm from the overlying capsule and approximately 12 cm from the cauterized resection margin. The uninvolved liver parenchyma is tan-brown and homogenous.

ORIENTED BY: Anatomic landmarks.

INTRAOPERATIVE FINDINGS: Gross only.

INKING:

- Liver capsule overlying mass: Black.
- Cauterized surgical margin: Blue.
- Area of tissue banking performed by surgeon: Green.

CASSETTES: Representative sections are submitted as follows:

- B1: Nodule #1 with overlying capsule.
- B2: Nodule #1 with adjacent uninvolved liver parenchyma.
- B3: Nodule #2 with closest approach to resection margin.
- B4: Nodule #2 with adjacent uninvolved liver parenchyma and overlying capsule.
- B5: Nodule #3 with adjacent uninvolved liver parenchyma and overlying capsule.
- B6: Uninvolved liver parenchyma, peripheral.
- B7: Uninvolved liver parenchyma, central.
- B8: Vascular and bile duct resection margins, en face.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the

They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes, and were necessary to reach a final diagnosis in this case. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Pathology PDF Report

Show images for Surgical Pathology

(enter 1 per line): 1. gallbladder, 2. left hepatic lobe

Authorizing Provider Information

Signed by

[REDACTED]

[page 4 of 5]
Signed

Date/Time

Phone

Pager

Result History

Surgical Pathology

(enter 1 per line): 1. gallbladder, 2. left hepatic lobe

This is NOT a Requisition. Requisition hyperlink below.

Surgical Pathology

(enter 1 per line): 1.

gallbladder, 2. left hepatic lobe

Authorizing:

Pathology and Cytology

Department:

Show images for Surgical Pathology

(enter 1 per line): 1. gallbladder, 2. left hepatic lobe

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Release Information

Released On

Released By

Order Details

Frequency
Once

Duration
1 occurrence

Priority
Routine

Order Class
Unit Collect

Order Questions

Question

Specimen

(enter 1 per line)

1. gallbladder
2. left hepatic lobe
hepatocellular
carcinoma

Lab Collection and Receipt Information

Collect Date

Collect Time

Collected By

Lab Receipt Date

Lab Receipt Time

Collection Information

Resulting Agency

Order Provider Info

[page 5 of 5]
	Office phone	Pager/beeper	E-mail
Ordering User			--
Authorizing Provider			--
Billing Provider			--

Electronically Signed By:

Electronically Authorized By

Electronically Ordered By

Acknowledgement Info

For

At

Acknowledged By

Acknowledged On

Order Status

Parent Status: Completed

Child Orders

(This order does not yet have any children)

Order RequisitionSurgical Pathology (enter 1 per line): 1. gallbladder, 2. left hepatic lobe

Criteria	lw 8/31/13	Yes	No

Source: NCI Genomic Data Commons file 349a3745-2dc7-4351-8351-dfdf25a004d2 (TCGA-UB-A7MB.8B239487-4D0E-45EF-84EB-F61B23C42FE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).